Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A02N, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A02N-01A (Primary Tumor).

Internal Sample IE . .

Taking into account the clinical and topographical data, item I. of the material presented is a rectal preparation with an invasive, poorly differentiated rectal carcinoma, partially of the type of a mucous carcinoma (G 3) with permeation of all wall layers (p T 3) and with lymphatic vessel invasion (L 1), as well as free resection margins and a free resection margin and a free ligature area together with free lymph nodes (0/12) (p N 0),

in addition, item II is fatty connective tissue with lymphoid cell elements corresponding to free lymph nodes

and in item III, reported clinically as a distal anastomosis ring, there is cryptal mucosa with focal moderate chronic inflammation and focal prominent vascular complexes.

Tumor classification:

ICD-O-DA M-8140/3

G 3, p T 3, L 1, p N 0.

ICD-0-3

Path carcinoma, mucinous 8480/3

CQCF adenocarcinoma, NOS 8140/3

Site: Rectum C20.9 pr 3/31/11

Laterality Discrepancy		X
Major Histology History		X
Reviewer Initials	Kma	Shelley

Source: NCI Genomic Data Commons file e7f1d426-de7e-4f92-9a29-8a154839006a (TCGA-AG-A02N.99A8B837-B8A9-48A7-A97D-D2EF2E882D60.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).